TCGA case TCGA-30-1891 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a2ca7b8-729d-4fab-a6f3-a5d1e5d1f4f3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 914 days (2.5 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.2 years (22,344 days); Year of diagnosis: 2004; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 1-10 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 141 days; Number of cycles: 7; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 141 days; Number of cycles: 7; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 189 days; Days to treatment end: 330 days; Number of cycles: 6; Treatment dose: 40 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 358 days; Days to treatment end: 386 days (1.1 years); Treatment dose: 10 mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 358 days; Days to treatment end: 386 days (1.1 years); Number of cycles: 2; Treatment dose: 50 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 400 days (1.1 years); Days to treatment end: 453 days (1.2 years); Number of cycles: 5; Treatment dose: 700 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 460 days (1.3 years); Days to treatment end: 526 days (1.4 years); Number of cycles: 4; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 460 days (1.3 years); Days to treatment end: 526 days (1.4 years); Number of cycles: 4; Treatment dose: 700 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 554 days (1.5 years); Days to treatment end: 638 days (1.7 years); Number of cycles: 5; Treatment dose: 75 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 666 days (1.8 years); Days to treatment end: 694 days (1.9 years); Number of cycles: 4; Treatment dose: 80 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 701 days (1.9 years); Days to treatment end: 890 days (2.4 years); Number of cycles: 12; Treatment dose: 3 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 855 days (2.3 years); Days to treatment end: 890 days (2.4 years); Number of cycles: 6; Treatment dose: 25 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 61.7 years (22,525 days); Days to diagnosis: 181 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 536 days (1.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 181 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 181 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 914 days (2.5 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-30-1891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-30-1891-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 20.
  Slide TCGA-30-1891-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20.
- Sample TCGA-30-1891-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 5, Route of administrations: Route of administration: IP.
- Drug treatment 8: Pharmaceutical therapy drug name: Cytoxan; Therapy regimen: Progression.
- Drug treatment 8, Route of administrations: Route of administration: PO.
- Drug treatment 9: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 12: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 914 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 914 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 181 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-30-1891-01A-01D-0648-01): tumor purity 0.78, ploidy 1.86, whole-genome doublings 0.
